Somatic mutation profile of tumor specimen MBCProject_2991_T1B_WES (aliquot MBCProject_2991_T1B_WES_1) from CMI case MBCProject_2991, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 65.1 years (23,767 days).
Specimen MBCProject_2991_T1B_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6743893d-2b56-48ee-95c5-81043802652f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2991_SALIVA (Saliva), aliquot MBCProject_2991_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52a9f38d-a7db-497b-bcdb-54c04d1c75cc

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Splice Site 2, 5'UTR 1, Frame Shift Del 1, Nonsense Mutation 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD35 | c.2128G>A p.A710T | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs782190439, COSV62909764; called by muse, mutect2
- FSTL5 | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1174499057; called by muse, mutect2, varscan2
- IGFN1 | c.2695G>A p.V899M (on ENST00000295591 / NM_001367841.1; = p.V3356M on NM_001164586.2) | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as rs375687736; called by muse, mutect2
- PCDHB13 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 10/221 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV53394015, COSV53399236; called by muse, mutect2
- PCGF3 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100745412; called by muse, mutect2
- PLEC | c.6116C>T p.S2039L (on ENST00000322810 / NM_201380.4; = p.S1929L on NM_000445.5) | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as rs781817576; ClinVar: uncertain significance; called by muse, mutect2
- PRL | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs751952340, COSV60591543; called by muse, mutect2, varscan2
- TEX15 | c.6310C>T p.Q2104* (on ENST00000256246; = p.Q2487* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 19/162 reads (12%) | catalogued as rs773218994; called by muse, mutect2, varscan2
- ARPP21 | c.545+1G>A p.X182_splice | Splice Site (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- CDH1 | c.595dup p.T199Nfs*10 | Frame Shift Ins (INS) | VAF 26/243 reads (11%) | called by mutect2, pindel, varscan2
- PAGR1 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2
- POLQ | c.5135_5141del p.A1712Vfs*15 | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | called by mutect2, pindel, varscan2
- RBM12 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTF1 | c.199-10_199delinsTTTTTTTTTTT p.X67_splice | Splice Site (ONP) | VAF 5/53 reads (9%) | called by mutect2*, pindel
- STAT5A | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.869); called by muse, mutect2
- TNIP3 | c.79G>C p.D27H (on ENST00000509841 / NM_001244764.2; = p.D20H on NM_001128843.2) | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ABCA12 | c.4800A>G p.Q1600= (on ENST00000272895 / NM_173076.3; = p.Q1282= on NM_015657.3) | Silent (SNP) | VAF 15/298 reads (5%) | catalogued as rs766425551; called by muse, mutect2
- AKAP11 | c.2913G>A p.L971= | Silent (SNP) | VAF 11/155 reads (7%) | called by muse, mutect2
- POLR3E | c.585C>T p.F195= | Silent (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- ABHD3 | c.555+339del | Intron (DEL) | VAF 16/152 reads (11%) | catalogued as rs754637613; called by mutect2, varscan2
- PLEKHB2 | c.-14C>T | 5'UTR (SNP) | VAF 19/155 reads (12%) | catalogued as COSV99301683; called by muse, mutect2, varscan2
